Surgical pathology report (de-identified scan), TCGA case TCGA-14-0787, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-0787-01A (Primary Tumor).

[page 1 of 2]
AP Report

* Final Report *

Document Type: AP Report
Document Date:
Document Status: Auth (Verified)
Document Title: Anatomic Pathology Report
Encounter info:

* Final Report *

Anatomic Pathology Report

Patient: ,

Accession Number:

Patient Number:

Financial Number:

Room/Bed: PT:

Admitting Physician:

Ordering Physician:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, RIGHT PARIETAL, CRANIOTOMY, FS1A: GLIOBLASTOMA MULTIFORME.
2. BRAIN, RIGHT PARIETAL, CRANIOTOMY: GLIOBLASTOMA MULTIFORME.

SPECIMEN:

1. Right parietal brain tumor.
2. Right parietal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

NAME OF OPERATION: Right craniotomy for brain tumor.

PREOPERATIVE DIAGNOSIS: Brain tumor.

GROSS DESCRIPTION:

Specimen #1 is received fresh for intraoperative consultation, labeled with the patient's name, hospital number and as "right parietal brain tumor." The specimen consists of several pieces of soft, brown-red tissue measuring approximately 1.0 x 1.0 x 0.5 mm. A portion of the tumor is frozen and

[page 2 of 2]
AP Report

[REDACTED], [REDACTED] - [REDACTED]

* Final Report *

submitted in cassette "FS1A." The remainder of the tissue is submitted in its entirety in cassette "1B."

Specimen #2 is received in formalin, labeled with the patient's name, hospital number and as "right parietal brain lesion." The specimen consists of multiple fragments of soft, grey, hemorrhagic tissue measuring approximately 1.5 x 1.0 x 0.5 cm in diameter. The specimen is submitted in its entirety in cassette "2A."

[REDACTED]

INTRAOPERATIVE CONSULTATION:

FS1A: RIGHT PARIETAL BRAIN TUMOR (FROZEN SECTION): GLIOBLASTOMA MULTIFORME.

[REDACTED]

TISSUE COMMITTEE CODE:

1

ICD-9 CODES:

191.9

[REDACTED]

Source: NCI Genomic Data Commons file eac9a293-a1ac-47c2-a2be-aefb6027f88c (TCGA-14-0787.46BD5D64-24B5-4519-AAFF-79A1240AE25E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).